Surgical pathology report (de-identified scan), TCGA case TCGA-XU-A92T, project TCGA-THYM (Thymoma), tissue source site University Health Network, specimen TCGA-XU-A92T-01A (Primary Tumor).

[page 1 of 3]
Patient Name:

MRN:

DOB:

Gender:F

Service:

Visit #:

Location:

Referring MD:

Collected:

Resulted:

Ordering MD:

Surgical Pathology Consultation Report

SPECIMEN(S) RECEIVED

1. Lymph-Node: Superior Mediastinal
2. Anterior mediastinal tumour and thymus gland

ICD-O-3
Thymoma, type AB, malignant
8582/3
Site: Thymus C379
JH 4/2/14

DIAGNOSIS

1. Lymph nodes, resection (superior mediastinal):
- Two lymph nodes, negative for malignancy (0/2)
2. Thymus, resection (anterior mediastinal resection and thymus gland):
- a) Thymoma, type AB, with: (see Comment)
- i) Greatest tumor dimension = 6.4 cm
- ii) Foci of microscopic transcapsular invasion present, with tumor cells focally <0.1 cm from a painted surface
- b) Thymic tissue with involutional changes

SYNOPTIC DATA

Specimen:	Thymus
Procedure:	Thymectomy
Specimen Integrity:	Intact
Specimen Weight:	93.7(g)
Tumor Size:	Greatest dimension: 6.4 cm Additional Dimension: 5.5 cm Additional Dimension: 4.3 cm
Histologic Type:	Type AB thymoma
Tumor Extension:	Other: foci of microscopic
transcapsular extension	
Margins:	Margins uninvolved by tumor Distance of tumor from closest
margin: 1 mm	
Treatment Effect:	Not applicable
Lymph-Vascular Invasion:	Not identified
Regional Lymph Nodes:	No regional lymph node metastases

Status: complete

Page: 1 of 3

[page 2 of 3]
Patient Name:

MRN: :

DOB: :

Gender: F

Service: :

Visit #: :

Location: :

Facility: :

Collected: :

Resulted: :

Ordering MD: :

Number examined: 2

Number involved: 0

Pathologic Staging (Modified Masaoka):

Stage IIa: Microscopic transcapsular

invasion

Implants/Distant Metastasis:

Cannot be assessed

Additional Pathologic Findings:

Age-appropriate involution changes

Other: focal infarction/necrosis in

tumor

COMMENT

2. Sections show an encapsulated tumor composed of areas of epithelioid cells admixed with small lymphocytes, interspersed with areas of bland spindle cells with only rare lymphocytes. Areas of tumor infarction/necrosis are noted, comprising approximately 15% of the tumor area examined in histologic sections. In several sections, microscopic transcapsular extension of tumor cells is identified, with tumor cells present focally <0.1 cm from the painted surface of the specimen, although it is unclear whether this surface represents a true resection margin. By immunohistochemistry, the epithelioid and spindled cells stain positive for cytokeratins (AE1/AE3) and P63, and negative for CD5. The small lymphocytes stain positive for CD5 and CD1a. The overall findings are in keeping with type AB thymoma, with microscopic transcapsular extension (modified Masaoka stage IIa).

ELECTRONICALLY VERIFIED BY: :

CLINICAL HISTORY

Thymoma

GROSS DESCRIPTION

1. The specimen container is labeled with the patient's name and as "superior mediastinal lymph node" contains a piece of fibroadipose tissue measuring 1.8 x 0.7 x 0.5 cm. Within the fatty tissue, two lymph nodes are identified grossly measuring 0.4 x 0.4 x 0.3 and 0.7 x 0.6 x 0.5 cm. 1A two lymph nodes submitted in toto

Status: complete

Page: 2 of 3

[page 3 of 3]
Patient Name:.

MRN:

Service:

Collected:

DOB:

Visit #:

Resulted:

Gender:F

Location:

Facility:

Ordering MD:

2. The specimen container is labeled with the patient's name and as "anterior mediastinal tumor and thymus gland" contains an unoriented thymus gland with and overall dimensions of 11.5 x 6.2 x 4.5 cm and weighs 93.7 g. The external surface of the specimen is painted with silver nitrate. A well-circumscribed mass is identified on the central aspect of the thymus gland measuring 6.4 x 5.5 x 4.3 cm. The mass is encapsulated, with the cut surface tan in color, multinodular and has a slightly soft and flabby consistency. The rest of the cut surface of the thymus gland is predominantly fatty with no other nodules identified grossly. Representative sections are submitted as follows:

2A-2F representative section of the mass

2G-2I representative section thymus tissue

Multiple pieces of the tumor are stored frozen.

Additional blocks

2J 2M additional representative section mass

12/12/13

12/13/13

Status: complete

Page: 3 of 3

Source: NCI Genomic Data Commons file 86e25596-ed21-4ccb-9d1b-5b8c50cffc72 (TCGA-XU-A92T.43A21213-AE07-4971-8A3C-77904C0E96BD.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).